Somatic mutation profile of tumor specimen 0DITT7 from CCDI case PBBWAD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.4 years (5,993 days).
Specimen 0DITT7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7641a54-de2f-4f1d-9133-02ac9c9a66ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DITSF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9fcfc60-8bd3-4b77-881c-a10bd5882750

The open-access MAF lists 46 somatic variants for this specimen: 24 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 14, Intron 3, 5'UTR 3, Splice Site 2, 3'UTR 2, Frame Shift Del 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 472/495 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 138/715 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs746685392, COSV56642005, COSV56643302; called by muse, mutect2, varscan2
- ANO2 | c.1003C>T p.R335C (on ENST00000356134 / NM_001278597.3; = p.R339C on NM_001278596.3) | Missense Mutation (SNP) | VAF 128/613 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs372991029, COSV59050232; called by muse, mutect2, varscan2
- BCO1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 40/1631 reads (2%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV99258471; called by muse, mutect2
- CASS4 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 360/750 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs777600668, COSV100824552, COSV64386691; called by muse, mutect2, varscan2
- CEP162 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 215/1188 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs537110398; called by muse, mutect2, varscan2
- KIAA1671 | c.2843G>A p.R948Q | Missense Mutation (SNP) | VAF 191/323 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1264456859; called by muse, mutect2, varscan2
- MATK | c.385G>A p.G129S (on ENST00000310132 / NM_139355.3; = p.G130S on NM_002378.4) | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs1457650257; called by muse, mutect2
- MED12 | c.133_144del p.F45_Q48del | In Frame Del (DEL) | VAF 412/1006 reads (41%) | catalogued as rs199469693, COSV61335196; ClinVar: not provided; called by mutect2, varscan2
- MUC16 | c.18779C>T p.A6260V | Missense Mutation (SNP) | VAF 186/667 reads (28%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs772779309; called by muse, mutect2, varscan2
- NDUFAF7 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 314/1058 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs770110937; called by muse, mutect2, varscan2
- CABIN1 | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 27/1065 reads (3%) | called by muse, mutect2
- CAPRIN2 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 265/880 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- CD274 | c.723G>T p.L241F | Missense Mutation (SNP) | VAF 332/1514 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDKL2 | c.1310T>A p.I437N | Missense Mutation (SNP) | VAF 34/1304 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- CDON | c.611A>G p.E204G | Missense Mutation (SNP) | VAF 771/1816 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FAT1 | c.5925T>A p.S1975R | Missense Mutation (SNP) | VAF 195/1044 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- GUCY2C | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 250/841 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HHLA2 | c.419-1G>A p.X140_splice | Splice Site (SNP) | VAF 276/1234 reads (22%) | called by muse, mutect2, varscan2
- LCE1C | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 189/988 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- OR51I2 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 150/585 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- RBM47 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SUCLA2 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 351/1001 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- UGT2B15 | c.1402del p.V468Sfs*27 | Frame Shift Del (DEL) | VAF 214/1119 reads (19%) | called by mutect2, varscan2
- ABCA8 | c.1527C>T p.G509= | Silent (SNP) | VAF 345/1177 reads (29%) | catalogued as rs766012830; called by muse, mutect2, varscan2
- ABHD16A | c.1521C>T p.H507= | Silent (SNP) | VAF 158/790 reads (20%) | catalogued as rs781751649; called by muse, mutect2, varscan2
- ABHD17C | c.786T>G p.S262= | Silent (SNP) | VAF 202/776 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.135C>T p.I45= | Silent (SNP) | VAF 263/407 reads (65%) | catalogued as COSV66308301; called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 16/392 reads (4%) | catalogued as rs1167537044; called by muse, mutect2
- DNAH8 | c.10266C>T p.F3422= | Silent (SNP) | VAF 38/1382 reads (3%) | called by muse, mutect2
- GDF10 | c.873C>T p.A291= | Silent (SNP) | VAF 26/203 reads (13%) | catalogued as rs782759947; called by muse, mutect2, varscan2
- IQCJ | c.354G>A p.G118= | Silent (SNP) | VAF 168/855 reads (20%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2487T>C p.S829= | Silent (SNP) | VAF 313/1580 reads (20%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.123G>A p.A41= | Silent (SNP) | VAF 143/568 reads (25%) | catalogued as rs763180228, COSV66934112; called by muse, mutect2, varscan2
- NPAP1 | c.558G>A p.S186= | Silent (SNP) | VAF 63/443 reads (14%) | catalogued as rs139317336; called by muse, mutect2, varscan2
- PCDH19 | c.2982T>C p.S994= (on ENST00000373034 / NM_001184880.2; = p.S946= on NM_020766.3) | Silent (SNP) | VAF 150/750 reads (20%) | catalogued as COSV55263495; called by muse, mutect2, varscan2
- PRICKLE2 | c.483C>T p.S161= (on ENST00000295902; = p.S105= on NM_198859.4) | Silent (SNP) | VAF 247/1297 reads (19%) | catalogued as rs780348941; called by muse, mutect2, varscan2
- SEPTIN4 | c.987C>T p.S329= | Silent (SNP) | VAF 73/248 reads (29%) | catalogued as rs775109901, COSV58729113; called by muse, mutect2, varscan2
- ABHD17C | c.*52T>C | 3'UTR (SNP) | VAF 52/151 reads (34%) | called by muse, mutect2, varscan2
- ACSM2B | c.1509+49C>T | Intron (SNP) | VAF 48/277 reads (17%) | called by muse, mutect2
- CHST7 | c.-13G>T | 5'UTR (SNP) | VAF 85/413 reads (21%) | called by muse, mutect2, varscan2
- FAM153CP | n.597+10C>T | Intron (SNP) | VAF 306/1508 reads (20%) | called by muse, mutect2, varscan2
- GLE1 | c.-25C>T | 5'UTR (SNP) | VAF 29/112 reads (26%) | called by muse, mutect2, varscan2
- MPP1 | c.-97A>G | 5'UTR (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- SQOR | c.*69G>A | 3'UTR (SNP) | VAF 67/197 reads (34%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3747C>A | Intron (SNP) | VAF 304/490 reads (62%) | catalogued as rs761846019; called by muse, mutect2, varscan2
